Somatic mutation profile of tumor specimen TCGA-B5-A3FC-01A (aliquot TCGA-B5-A3FC-01A-11D-A228-09) from TCGA case TCGA-B5-A3FC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 53.2 years (19,422 days).
Specimen TCGA-B5-A3FC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2b8c8dd-90d3-454e-9970-7ac4ae93df16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A3FC-10A (Blood Derived Normal), aliquot TCGA-B5-A3FC-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa22c0a7-7e06-4574-9f78-cb42b836db98

The open-access MAF lists 15,315 somatic variants for this specimen: 10,900 protein-altering or splice-affecting, 4,100 silent, 315 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9,579, Silent 4,100, Nonsense Mutation 587, Frame Shift Ins 373, Splice Site 164, Intron 139, Splice Region 126, RNA 73, Frame Shift Del 61, 3'UTR 33, 3'Flank 26, 5'UTR 23.

Variants (750 of 15,315; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAAS | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758440592, CM055898, CM065946, COSV52932932; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.5318C>T p.A1773V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs760549861, CM087708, CM1210213, COSV64670966; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.3703C>T p.R1235W | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs63750402, CM053086, COSV52745762; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACADVL | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs118204016, CM990097, COSV50038912; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHI1 | c.96dup p.L33Tfs*9 | Frame Shift Ins (INS) | VAF 30/91 reads (33%) | catalogued as rs747322175; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- ANOS1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 31/113 reads (27%) | catalogued as rs1555893221, CM930451; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AQP2 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs104894330, CM970100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.9697C>T p.R3233* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs199422194, CM092386; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.6100C>T p.R2034* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs532480170, CM960102, COSV53736160; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCL10 | c.136dup p.I46Nfs*4 | Frame Shift Ins (INS) | VAF 14/49 reads (29%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- BEST1 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs281865214, CM001376, COSV57120144; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BEST1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28940570, CM000841, CM1414063; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.2588dup p.N863Kfs*18 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | catalogued as rs80359335; ClinVar: pathogenic; called by mutect2, varscan2
- CAPN3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224958, CM040389, COSV58819321; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as rs377177061; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CDC45 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs540217942; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDHR1 | c.1527T>G p.Y509* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as rs1477733493; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CHD8 | c.3724C>T p.R1242* (on ENST00000646647 / NM_001170629.2; = p.R963* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as rs1555314788, COSV67872855; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHEK1 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as rs772079899; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL1A2 | c.3034G>A p.G1012S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72659319, CM930157, COSV51957475; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.5356C>T p.R1786C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1555471394, COSV52135847; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- DCX | c.-22-364C>T | Intron (SNP) | VAF 25/82 reads (30%) | catalogued as rs761786389; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DDC | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771317809, CM077526; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DHX30 | c.1478G>A p.R493H (on ENST00000445061 / NM_138615.3; = p.R454H on NM_014966.3) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519436, COSV53140099; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DKC1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs199422249, CM060958; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- DYRK1A | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as rs1057518204, CM162102, COSV100117767, COSV58296087; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPM2A | c.953dup p.Q319Pfs*12 | Frame Shift Ins (INS) | VAF 20/76 reads (26%) | catalogued as rs587776554; ClinVar: pathogenic; called by pindel, varscan2
- EYA1 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as rs121909202, CM061734; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FANCM | c.2589dup p.D864Rfs*4 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | catalogued as rs768006618; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FBN1 | c.8038C>T p.R2680C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs794728283, CM930248, COSV100355798; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 42/87 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747502397, COSV60645207, COSV60646793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGFR3 | c.*918G>A | 3'UTR (SNP) | VAF 32/65 reads (49%) | catalogued as rs121913113, CM065183, COSV53404768; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FKRP | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28937905, CM040123, COSV59360232; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GABRG2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.997); catalogued as rs796052505, COSV62721686; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GATAD2B | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as rs761820222; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- GFPT1 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.638); catalogued as rs775399768; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNAS | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs1131691999, CM013729, CM013730, COSV55691267; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 16/55 reads (29%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- GUSB | c.1617C>T p.S539= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as rs377519272, CS951430; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HEXA | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121907966, CM920341; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HMBS | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs118204107, CM930402, COSV53827470, COSV99597969; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSD17B3 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs119481078, CM981003; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LMNA | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs57318642, CM033972; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LMX1B | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs886039576, CM042391, COSV62742576; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MED13L | c.5278C>T p.R1760* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as rs886041448, COSV99929718; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as rs770330684; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MUSK | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as rs1487680236, COSV99504793; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs397516127, CM031273, CM973126, COSV62516387; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NF1 | c.3916C>T p.R1306* | Nonsense Mutation (SNP) | VAF 52/72 reads (72%) | catalogued as rs376576925, CM981381, COSV62193951; ClinVar: pathogenic; called by muse, varscan2
- NR2E3 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489149705, CM000533, COSV100489463; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.4411C>T p.R1471* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as rs570278338, CM030071, CM032972, COSV61786705; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OCRL | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as rs1556346316, CM990983, COSV63980169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.1091dup p.Y366Lfs*10 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | catalogued as rs758946412; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1381C>T p.R461* (on ENST00000521381 / NM_181523.3; = p.R191* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs1057519838, COSV57125001; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PLA2G6 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs121908685, CM063030, COSV59267862; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PLOD1 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as rs121913550, CM920580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 31/89 reads (35%) | catalogued as rs63750451, CM061906; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POMT1 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs119462987, CM061917; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PSTPIP1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs121908130, CM020748, COSV51198632; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PYCR1 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs139751598, CM095498; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RFT1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753527390, COSV56250381; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.7160C>T p.A2387V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs794728754, CM133736, COSV100770994; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SALL1 | c.1763dup p.G589Rfs*6 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | catalogued as rs1057518232; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN2A | c.605+1G>A p.X202_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | catalogued as rs796053171, COSV104393161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.3694C>T p.R1232W (on ENST00000333535 / NM_198056.3; = p.R1231W on NM_000335.5) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs199473207, CM983679, COSV100346639, COSV61120841; ClinVar: uncertain significance / not provided / pathogenic; called by muse, mutect2, varscan2
- SCO1 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774730754; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPAST | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs878854990, CM042786, CM101457, COSV59518285; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 12/43 reads (28%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- SYNGAP1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs1554121443; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TAZ | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1085307797, CM024152, CM046066, COSV100173351; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TBX6 | c.704dup p.M236Hfs*44 | Frame Shift Ins (INS) | VAF 19/51 reads (37%) | catalogued as rs758051786; ClinVar: pathogenic; called by mutect2, varscan2
- TCF4 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1568303352, CM091864, COSV61890423; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TSC2 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747237113; ClinVar: likely pathogenic / likely benign; called by muse, mutect2, varscan2
- TTN | c.39361C>T p.R13121* (on ENST00000591111; = p.R5697* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs770767998, CM1514711, COSV60237971; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- WASF1 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as rs1562159562, COSV100846939; ClinVar: pathogenic; called by muse, mutect2
- WT1 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs1423753702, CM971594, COSV60067818, COSV60068249, COSV60071382, COSV60073329, COSV60074859, COSV60075137; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3190A>G p.T1064A | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.133); catalogued as COSV59383171; called by muse, mutect2, varscan2
- A4GALT | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs756022687; called by muse, varscan2
- A4GALT | c.963C>A p.S321R | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV50745374; called by muse, varscan2
- AACS | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.184); catalogued as rs1049043798; called by muse, mutect2, varscan2
- AADACL4 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as rs757095087; called by muse, mutect2, varscan2
- AAK1 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1288732136, COSV68646006; called by muse, mutect2, varscan2
- AAK1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1354922669, COSV68646998; called by muse, mutect2, varscan2
- AANAT | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs755534498; called by muse, mutect2, varscan2
- AARS1 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs372221218; ClinVar: uncertain significance; called by muse, varscan2
- AARS1 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as rs752548366; called by muse, varscan2
- AARS2 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767041217; called by muse, mutect2, varscan2
- AARS2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767748655; called by muse, mutect2, varscan2
- ABAT | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755435740, COSV51620243; called by muse, mutect2, varscan2
- ABCA1 | c.6013G>A p.E2005K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66071095; called by muse, mutect2, varscan2
- ABCA12 | c.6712C>T p.R2238W (on ENST00000272895 / NM_173076.3; = p.R1920W on NM_015657.3) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs756459081, COSV55950569; called by muse, mutect2, varscan2
- ABCA12 | c.4279G>A p.D1427N (on ENST00000272895 / NM_173076.3; = p.D1109N on NM_015657.3) | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.652); catalogued as rs761801135; called by muse, mutect2, varscan2
- ABCA2 | c.4159G>A p.A1387T (on ENST00000614293; = p.A1357T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs764315344; called by muse, mutect2, varscan2
- ABCA2 | c.1970G>A p.R657H (on ENST00000614293; = p.R627H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1194343034, COSV55803004; called by muse, mutect2, varscan2
- ABCA6 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as rs753896538, COSV52638699, COSV52642214; called by muse, mutect2, varscan2
- ABCA7 | c.4262dup p.R1422Pfs*105 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | catalogued as rs768628795; called by mutect2, pindel, varscan2
- ABCA7 | c.4792G>A p.V1598M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs748081008, COSV54034818; called by muse, mutect2, varscan2
- ABCA8 | c.302-2A>C p.X101_splice | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as rs752947207; called by muse, mutect2, varscan2
- ABCA9 | c.4685G>A p.R1562Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs372952180; called by muse, mutect2, varscan2
- ABCA9 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV60629921; called by muse, mutect2, varscan2
- ABCB1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs28381902; called by muse, mutect2, varscan2
- ABCB7 | c.1085C>T p.T362M (on ENST00000373394 / NM_001271696.3; = p.T363M on NM_004299.6) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs1029747021; called by muse, varscan2
- ABCB7 | c.203G>T p.R68I (on ENST00000373394 / NM_001271696.3; = p.R69I on NM_004299.6) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV53721792; called by muse, mutect2, varscan2
- ABCB8 | c.1871G>A p.R624Q (on ENST00000297504 / NM_001282291.2; = p.R607Q on NM_007188.5) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199779363; called by muse, mutect2, varscan2
- ABCC1 | c.3443G>A p.R1148H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748686682; called by muse, mutect2, varscan2
- ABCC11 | c.3593G>A p.R1198Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); catalogued as rs369304577; called by mutect2, varscan2
- ABCC11 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs200134154; called by mutect2, varscan2
- ABCC12 | c.3853G>A p.A1285T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs771541274, COSV60911476; called by muse, mutect2, varscan2
- ABCC12 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs955579071; called by muse, mutect2, varscan2
- ABCC2 | c.890dup p.K298Efs*36 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs759781877; called by mutect2, varscan2
- ABCC2 | c.3922C>T p.R1308W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1024856612, COSV64987948; called by muse, mutect2, varscan2
- ABCC3 | c.3160C>T p.R1054C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs141068276, COSV99559517; called by muse, mutect2, varscan2
- ABCC3 | c.3323C>T p.T1108M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs199698625, COSV53330756; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCC6 | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398594452; called by muse, mutect2, varscan2
- ABCC8 | c.4600A>G p.T1534A | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as CM131668; called by muse, mutect2, varscan2
- ABCC9 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs759985677; called by muse, mutect2, varscan2
- ABCD1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781850760, COSV99497925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD2 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373640731; called by muse, mutect2, varscan2
- ABCE1 | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs745538246; called by muse, mutect2, varscan2
- ABCF3 | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV53051844; called by muse, mutect2, varscan2
- ABCF3 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771494683; called by muse, mutect2, varscan2
- ABCG1 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as rs761179577; called by muse, mutect2, varscan2
- ABCG2 | c.1737G>A p.T579= | Splice Region (SNP) | VAF 14/30 reads (47%) | catalogued as rs369116571, COSV52942823; called by muse, mutect2, varscan2
- ABCG4 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs1565817375; called by muse, mutect2, varscan2
- ABCG8 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 39/72 reads (54%) | catalogued as rs375005392, CM012309; called by muse, mutect2, varscan2
- ABHD12 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs749414680, COSV100194591; called by muse, mutect2, varscan2
- ABHD12 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs147888888; called by muse, varscan2
- ABHD14A-ACY1 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (1); catalogued as rs770851638; called by muse, mutect2, varscan2
- ABHD17A | c.589G>A p.V197M (on ENST00000292577 / NM_001130111.2; = p.V248M on NM_031213.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1287476745; called by muse, mutect2, varscan2
- ABI3 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as rs769714351, COSV56799151; called by muse, mutect2, varscan2
- ABI3BP | c.1495A>G p.T499A | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as rs778719617; called by muse, mutect2, varscan2
- ABI3BP | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751074977, COSV52536843, COSV99427604; called by muse, mutect2, varscan2
- ABLIM2 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs371380434; called by muse, mutect2, varscan2
- ABTB1 | c.707G>A p.R236H (on ENST00000232744 / NM_172027.3; = p.R94H on NM_032548.3) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs767792728; called by muse, mutect2, varscan2
- ABTB1 | c.1393C>T p.R465W (on ENST00000232744 / NM_172027.3; = p.R323W on NM_032548.3) | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs1228713820, COSV51740978; called by muse, mutect2, varscan2
- AC008397.2 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264438482, COSV53208745; called by muse, varscan2
- AC011462.1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs887411374; called by muse, varscan2
- AC092143.1 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59247998; called by muse, varscan2
- AC092143.1 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.197); catalogued as rs1344725531; called by muse, varscan2
- AC093246.1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs755457504; called by muse, varscan2
- AC093525.2 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | PolyPhen benign (0.017); catalogued as rs772098705; called by muse, mutect2, varscan2
- AC097636.1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774179158, COSV71309426; called by muse, mutect2, varscan2
- AC127029.3 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 95/347 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.952); catalogued as rs41295255; called by muse, mutect2, varscan2
- ACAA1 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs374655368; called by muse, mutect2, varscan2
- ACACA | c.6772C>T p.R2258C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761713389; called by muse, mutect2, varscan2
- ACACB | c.6985C>T p.R2329C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs560469698; called by muse, mutect2, varscan2
- ACAD10 | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs1251428097, COSV58158694; called by muse, mutect2, varscan2
- ACAD9 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs746494284; called by muse, mutect2, varscan2
- ACAD9 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as rs1266273831, COSV58306959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAD9 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs768894091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACADVL | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140629318, CM024582, CM990086, COSV50039777; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- ACAP1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs768382654; called by muse, mutect2, varscan2
- ACAP2 | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs147239672; called by muse, mutect2, varscan2
- ACBD3 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766741908, COSV64729849; called by muse, mutect2, varscan2
- ACCS | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV55460080; called by muse, mutect2, varscan2
- ACCSL | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as rs199703277, COSV66580585; called by muse, mutect2, varscan2
- ACCSL | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as rs746976918, COSV66580653; called by muse, mutect2, varscan2
- ACE | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as rs140129129; called by muse, varscan2
- ACHE | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1428177392, COSV53818193; called by muse, mutect2, varscan2
- ACKR2 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs760448133, COSV56177645; called by muse, mutect2, varscan2
- ACKR3 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1376323268, COSV56021220; called by muse, mutect2, varscan2
- ACKR3 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV56021742; called by muse, mutect2, varscan2
- ACLY | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs565573136, COSV100709760; called by muse, varscan2
- ACOT11 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139645585; called by muse, mutect2, varscan2
- ACOT2 | c.46A>G p.R16G | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs765220557, COSV53151793; called by muse, mutect2, varscan2
- ACOT7 | c.253G>A p.A85T (on ENST00000377855 / NM_181864.3; = p.A75T on NM_007274.4) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.097); catalogued as rs1314714440, COSV64111832; called by muse, mutect2, varscan2
- ACOX3 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs140412078; called by muse, mutect2, varscan2
- ACP3 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as rs769775568, COSV100668429, COSV63641046; called by muse, mutect2, varscan2
- ACP4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as rs765260771; called by muse, mutect2, varscan2
- ACP5 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as rs756201795, COSV99520328; called by muse, mutect2, varscan2
- ACP7 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV104402660; called by muse, mutect2, varscan2
- ACSBG1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as rs745602145, COSV99357826; called by muse, mutect2, varscan2
- ACSL4 | c.1355G>A p.R452Q (on ENST00000340800 / NM_022977.2; = p.R411Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.611); catalogued as rs776295981; called by muse, mutect2, varscan2
- ACSL5 | c.256G>A p.A86T (on ENST00000354273; = p.A142T on NM_016234.3) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs531114802, COSV61130953; called by muse, mutect2, varscan2
- ACSL6 | c.1638G>A p.P546= (on ENST00000379240; = p.P571= on NM_015256.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 13/40 reads (33%) | catalogued as rs368747747, COSV57295930; called by muse, varscan2
- ACSM1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs745476935, COSV54636001; called by muse, mutect2, varscan2
- ACSM4 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs370829685; called by muse, mutect2, varscan2
- ACSS1 | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs145929672; called by muse, mutect2, varscan2
- ACSS1 | c.1460T>C p.V487A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as rs1376536607; called by muse, mutect2
- ACTB | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.204); catalogued as COSV59319915; called by muse, mutect2, varscan2
- ACTN1 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV51990746; called by muse, mutect2, varscan2
- ACTN3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs374445358; called by muse, mutect2, varscan2
- ACTN3 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746507012; called by muse, mutect2, varscan2
- ACTN3 | c.2254C>T p.R752* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as rs763208690, COSV100074264, COSV100074529; called by muse, mutect2, varscan2
- ACTN4 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99400778; called by muse, varscan2
- ACTN4 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV53143698; called by muse, mutect2, varscan2
- ACTN4 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234222656, COSV53143783; called by muse, mutect2, varscan2
- ACTRT1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs1364789276; called by muse, mutect2, varscan2
- ACVR2A | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs375035474; called by muse, mutect2, varscan2
- ACVR2B | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV61702435; called by muse, mutect2, varscan2
- ADAM10 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs754468638; called by muse, mutect2, varscan2
- ADAM12 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as rs140163127; called by muse, mutect2, varscan2
- ADAM12 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs576203316, COSV64113235; called by muse, varscan2
- ADAM18 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs764655233, COSV99696195; called by muse, mutect2, varscan2
- ADAM28 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56097946; called by muse, mutect2, varscan2
- ADAM28 | c.890+1G>A p.X297_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as rs138768775; called by muse, mutect2, varscan2
- ADAM30 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.258); catalogued as rs777017829; called by muse, varscan2
- ADAM30 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1336336681; called by muse, mutect2, varscan2
- ADAM30 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); catalogued as rs1217237337; called by muse, mutect2, varscan2
- ADAM33 | c.735C>A p.D245E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs752230445; called by muse, mutect2, varscan2
- ADAM7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1333012683, COSV51535711; called by muse, mutect2, varscan2
- ADAMTS1 | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV53170986; called by muse, mutect2, varscan2
- ADAMTS1 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 39/111 reads (35%) | catalogued as rs944862656, COSV53169549; called by muse, mutect2, varscan2
- ADAMTS10 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54352849; called by muse, mutect2, varscan2
- ADAMTS12 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs551278824, COSV61256246; called by muse, mutect2, varscan2
- ADAMTS13 | c.4081C>T p.R1361W | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1345844859; called by muse, mutect2, varscan2
- ADAMTS14 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100941327; called by muse, mutect2, varscan2
- ADAMTS16 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760157335, COSV56996301; called by muse, mutect2, varscan2
- ADAMTS16 | c.2821C>T p.R941W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs746555489; called by muse, mutect2, varscan2
- ADAMTS17 | c.2624C>T p.A875V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.272); catalogued as rs749156998; called by muse, mutect2, varscan2
- ADAMTS17 | c.2242C>A p.L748M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV51479941; called by muse, mutect2, varscan2
- ADAMTS17 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs540647222, COSV51495472; called by muse, mutect2, varscan2
- ADAMTS19 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs188910013, COSV50731320; called by muse, mutect2, varscan2
- ADAMTS2 | c.3047G>A p.R1016H | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs746802388, COSV104380884; called by muse, mutect2, varscan2
- ADAMTS2 | c.2117G>A p.S706N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs980974590; called by muse, mutect2
- ADAMTS2 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs200806292; called by muse, varscan2
- ADAMTS2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs758348587, COSV51087034; called by muse, varscan2
- ADAMTS20 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1321782265, COSV101166050; called by muse, mutect2, varscan2
- ADAMTS3 | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371868606, COSV99710273; called by muse, mutect2, varscan2
- ADAMTS4 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs114728887, COSV100917865; called by muse, mutect2, varscan2
- ADAMTS4 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs749038765; called by muse, mutect2, varscan2
- ADAMTS5 | c.2145G>T p.K715N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.522); catalogued as COSV53181745; called by muse, mutect2, varscan2
- ADAMTS5 | c.1068G>T p.E356D | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs768117628; called by muse, mutect2, varscan2
- ADAMTS8 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748679085; called by muse, varscan2
- ADAMTS8 | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs199994390, COSV57293532; called by muse, varscan2
- ADAMTSL1 | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs780897867, COSV65894384; called by muse, mutect2, varscan2
- ADAMTSL2 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779112036, CM166984, COSV63203794; called by muse, mutect2
- ADARB1 | c.1888C>T p.R630W (on ENST00000360697 / NM_001346687.2; = p.R590W on NM_001112.4) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759280487; called by muse, mutect2, varscan2
- ADARB2 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as rs112668147; called by muse, mutect2, varscan2
- ADCK5 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs868957894; called by muse, mutect2
- ADCY1 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749480692, COSV52031461; called by muse, mutect2, varscan2
- ADCY1 | c.2971G>A p.A991T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52029881, COSV52032579; called by muse, mutect2, varscan2
- ADCY10 | c.3649C>T p.R1217C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs754372156, COSV63238479; called by muse, mutect2, varscan2
- ADCY3 | c.2528C>T p.T843M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs912577401, COSV53172302; called by muse, mutect2, varscan2
- ADCY3 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1285631837, COSV53168828; called by muse, varscan2
- ADCY5 | c.3376G>A p.G1126S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59194752; called by muse, mutect2, varscan2
- ADCY5 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs751504886, COSV59202843; called by muse, mutect2, varscan2
- ADCY6 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs779333538, COSV104410975; called by muse, mutect2, varscan2
- ADCY7 | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374814047, COSV54269509; called by muse, mutect2, varscan2
- ADCY9 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.374); catalogued as COSV99570647; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745856523, COSV58443114; called by muse, mutect2, varscan2
- ADD2 | c.1063A>G p.M355V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs782415400; called by muse, mutect2, varscan2
- ADGRA3 | c.2923T>C p.S975P | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1290822324; called by muse, mutect2, varscan2
- ADGRB2 | c.4283C>T p.P1428L | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs1429204385; called by muse, mutect2, varscan2
- ADGRB2 | c.2815G>A p.G939S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1165585659; called by muse, mutect2, varscan2
- ADGRD1 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99897530; called by muse, mutect2, varscan2
- ADGRE5 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs369840270; called by muse, mutect2, varscan2
- ADGRE5 | c.2204C>T p.A735V (on ENST00000242786 / NM_078481.4; = p.A642V on NM_001784.5) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs780589696, COSV54391434; called by muse, varscan2
- ADGRF3 | c.1978C>T p.R660* (on ENST00000311519 / NM_001145168.1; = p.R461* on NM_153835.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs116734873; called by mutect2, varscan2
- ADGRF3 | c.1405G>A p.G469R (on ENST00000311519 / NM_001145168.1; = p.G270R on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs375672733; called by muse, mutect2, varscan2
- ADGRF4 | c.892T>G p.L298V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs745953561, COSV51949608; called by muse, mutect2, varscan2
- ADGRG1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs767100119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRG1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs139207635; called by muse, mutect2, varscan2
- ADGRG4 | c.6571G>T p.A2191S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV99797936; called by muse, mutect2, varscan2
- ADGRG7 | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as COSV99841271; called by muse, mutect2, varscan2
- ADGRL1 | c.2495C>T p.T832M (on ENST00000340736 / NM_001008701.3; = p.T827M on NM_014921.5) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768079255, COSV61563795; called by muse, mutect2, varscan2
- ADGRV1 | c.6268C>T p.R2090C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs1374306116; called by muse, mutect2, varscan2
- ADGRV1 | c.16502C>A p.S5501Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV67980225; called by muse, mutect2, varscan2
- ADH1A | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs778783854; called by muse, mutect2, varscan2
- ADH1A | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.366); catalogued as COSV52925883; called by muse, mutect2, varscan2
- ADH4 | c.18+1G>A p.X6_splice | Splice Site (SNP) | VAF 30/87 reads (34%) | catalogued as rs770951929; called by muse, mutect2, varscan2
- ADIPOR1 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs750288767; called by muse, mutect2, varscan2
- ADK | c.830G>A p.R277Q (on ENST00000286621; = p.R260Q on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562751709, COSV54200858; called by muse, mutect2, varscan2
- ADPRHL1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.297); catalogued as rs761645929, COSV100733316; called by muse, mutect2, varscan2
- ADPRS | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs756440961; called by muse, mutect2, varscan2
- ADRA2B | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs570135294; called by muse, varscan2
- ADRM1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); catalogued as COSV53355338, COSV53357036; called by muse, mutect2, varscan2
- ADSL | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.978); catalogued as rs752735865, COSV53409230; called by muse, mutect2, varscan2
- AEBP1 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs376114999; called by muse, mutect2, varscan2
- AEBP2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.899); catalogued as rs1485556682, COSV99857666; called by muse, mutect2, varscan2
- AFDN | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs769754520, COSV60043738, COSV60062275; called by muse, mutect2, varscan2
- AFDN | c.3820C>T p.R1274C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.719); catalogued as rs768477295, COSV60057616; called by muse, mutect2, varscan2
- AFDN | c.4858C>T p.R1620C (on ENST00000447894 / NM_001366320.1; = p.R1618C on NM_001040000.3) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV60039779; called by muse, mutect2, varscan2
- AFF1 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1391954063; called by muse, mutect2, varscan2
- AFF4 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs755243717, COSV54800434; called by muse, mutect2, varscan2
- AFG3L2 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1340859041; called by muse, mutect2, varscan2
- AGA | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); catalogued as COSV99219336; called by muse, mutect2, varscan2
- AGAP4 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1465778476; called by muse, mutect2, varscan2
- AGAP4 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 127/488 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs1223088663; called by muse, varscan2
- AGAP6 | c.394G>A p.A132T (on ENST00000374056 / NM_001365867.1; = p.A155T on NM_001077665.2) | Missense Mutation (SNP) | VAF 121/377 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as rs782585572; called by muse, mutect2, varscan2
- AGAP6 | c.1222C>T p.R408W (on ENST00000374056 / NM_001365867.1; = p.R431W on NM_001077665.2) | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as rs782590376; called by muse, mutect2, varscan2
- AGBL1 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs753103295; called by muse, mutect2, varscan2
- AGBL5 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427970142, COSV59936017; called by muse, mutect2, varscan2
- AGL | c.3071A>G p.K1024R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs755500845; called by muse, mutect2, varscan2
- AGO2 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1297380320, COSV55049588; called by muse, mutect2, varscan2
- AGPS | c.1346del p.K449Sfs*15 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | catalogued as rs1559072835; called by mutect2, pindel, varscan2
- AGRN | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.113); catalogued as COSV65072519; called by muse, varscan2
- AGRN | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as rs532395667; called by muse, varscan2
- AGRN | c.4313C>T p.S1438L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1460707518; called by muse, mutect2, varscan2
- AGRN | c.4562G>A p.R1521H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs371871999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGT | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs772453722, COSV64184682; called by muse, mutect2, varscan2
- AGTPBP1 | c.2642C>T p.T881I (on ENST00000357081 / NM_001330701.2; = p.T841I on NM_015239.2) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61272415; called by muse, mutect2, varscan2
- AHCTF1 | c.4079C>T p.P1360L (on ENST00000366508; = p.P1334L on NM_015446.5) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs759251600; called by muse, mutect2, varscan2
- AHDC1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99898777; called by muse, mutect2, varscan2
- AHI1 | c.3364C>T p.R1122* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as rs1487081231, COSV55630779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK | c.10631C>T p.S3544F | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1253239548; called by muse, mutect2, varscan2
- AHNAK | c.3356G>A p.G1119D | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs755528839; called by muse, mutect2, varscan2
- AHNAK | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99947004; called by muse, mutect2, varscan2
- AHNAK | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.45); catalogued as rs560438050, COSV57224075; called by muse, mutect2, varscan2
- AHNAK | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs142247372; called by muse, mutect2, varscan2
- AHNAK2 | c.10378T>C p.S3460P | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1165999775; called by muse, mutect2, varscan2
- AHNAK2 | c.4996C>T p.P1666S | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100315735; called by muse, mutect2, varscan2
- AHNAK2 | c.2149G>T p.D717Y | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1380871684; called by muse, mutect2, varscan2
- AHNAK2 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537024957; called by muse, varscan2
- AHNAK2 | c.500A>G p.E167G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV60914023; called by muse, varscan2
- AHR | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757131411, COSV54122212; called by muse, mutect2, varscan2
- AHRR | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs751406178, COSV57084475; called by muse, mutect2, varscan2
- AHRR | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs939891417; called by muse, mutect2, varscan2
- AIMP2 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as rs374123170; called by muse, mutect2, varscan2
- AK8 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs146410308; called by muse, mutect2, varscan2
- AK9 | c.2969C>A p.P990H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58137723; called by mutect2, varscan2
- AKAP13 | c.6701G>A p.R2234H (on ENST00000394518 / NM_007200.5; = p.R2238H on NM_006738.6) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as rs750905368; called by muse, mutect2, varscan2
- AKAP17A | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1392318074; called by muse, mutect2
- AKAP4 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.06); catalogued as COSV100654167; called by muse, mutect2, varscan2
- AKAP5 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs762808533; called by muse, mutect2, varscan2
- AKAP6 | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766438234, COSV55208704; called by muse, mutect2, varscan2
- AKR1B10 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs753347797; called by muse, mutect2, varscan2
- AKR1C1 | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV101080427; called by muse, mutect2, varscan2
- AKR1D1 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs768685155; called by muse, mutect2
- AKR1E2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs376504041; called by muse, mutect2, varscan2
- AKT2 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs768539227, COSV60910808; called by muse, varscan2
- AL121899.2 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.425); catalogued as rs146171554, COSV101198371; called by muse, mutect2, varscan2
- AL121899.2 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs769875976; called by muse, mutect2, varscan2
- AL592490.1 | c.2203A>G p.I735V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1211408821; called by muse, mutect2, varscan2
- AL645922.1 | c.2065G>A p.V689I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774051674, COSV54959146; called by muse, mutect2, varscan2
- ALAS1 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as rs1191585292, COSV59629716; called by muse, mutect2, varscan2
- ALAS2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM095122, CM109565, COSV100238421, COSV100238671; called by muse, mutect2, varscan2
- ALB | c.1376G>A p.S459N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99890954; called by muse, mutect2, varscan2
- ALDH18A1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs1183327194; called by muse, varscan2
- ALDH18A1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1258297586; called by muse, varscan2
- ALDH1A1 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1057408909, COSV52792875; called by muse, mutect2, varscan2
- ALDH1B1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs61757680; called by muse, mutect2, varscan2
- ALDH1B1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs770591719, COSV66619291; called by mutect2, varscan2
- ALDH1L1 | c.2269A>G p.K757E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs138816561; called by muse, mutect2, varscan2
- ALDH2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs191240032; called by muse, mutect2, varscan2
- ALDH3B2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1140670, COSV62427836; called by muse, varscan2
- ALDH4A1 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766982473; called by muse, mutect2, varscan2
- ALDH5A1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139486423; called by muse, varscan2
- ALDH5A1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1561879312; called by muse, mutect2, varscan2
- ALDH8A1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.097); catalogued as rs188652133, COSV55641793; called by muse, mutect2, varscan2
- ALDH8A1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375471579; called by muse, mutect2, varscan2
- ALDOA | c.763C>T p.R255C (on ENST00000642816 / NM_001243177.4; = p.R201C on NM_184041.5) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs372394541, COSV57633972; called by muse, mutect2, varscan2
- ALDOC | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs182794210; called by muse, mutect2, varscan2
- ALG13 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1172385892; called by muse, mutect2, varscan2
- ALG3 | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1226905583; called by muse, mutect2, varscan2
- ALKBH1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746256948; called by muse, mutect2, varscan2
- ALKBH4 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs766828985; called by mutect2, varscan2
- ALKBH5 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67687383; called by muse, mutect2, varscan2
- ALOX12B | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs376969209, COSV59871270, COSV59877543; called by muse, mutect2, varscan2
- ALOX5 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs771513019, COSV65552457; called by muse, mutect2, varscan2
- ALPK3 | c.4318C>T p.R1440C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.517); catalogued as rs200672174, COSV51932489; called by muse, mutect2, varscan2
- AMACR | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747252381, COSV56872035; called by muse, mutect2
- AMER1 | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 68/218 reads (31%) | catalogued as COSV57654119; called by muse, mutect2, varscan2
- AMIGO2 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV56975844; called by muse, mutect2, varscan2
- AMIGO3 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.097); catalogued as rs1194818995; called by muse, mutect2, varscan2
- AMOT | c.1927C>T p.R643C (on ENST00000371959 / NM_001113490.1; = p.R234C on NM_133265.3) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1414246520, COSV59068047; called by muse, mutect2, varscan2
- AMOT | c.1540C>T p.R514C (on ENST00000371959 / NM_001113490.1; = p.R105C on NM_133265.3) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142235994, COSV59061402; called by muse, mutect2, varscan2
- AMPD1 | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781393982, COSV62416081; called by muse, mutect2, varscan2
- AMPD1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147852547; called by muse, mutect2, varscan2
- AMPD2 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs772196474; called by muse, mutect2, varscan2
- AMPD2 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56648823; called by muse, mutect2, varscan2
- AMPD3 | c.524G>A p.R175Q (on ENST00000396553 / NM_001025389.2; = p.R184Q on NM_000480.3) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs762205591; called by muse, mutect2, varscan2
- AMPH | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs766808058, COSV57738609; called by muse, mutect2, varscan2
- AMY2A | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV101340610; called by muse, mutect2, varscan2
- AMY2A | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV70214819; called by muse, mutect2, varscan2
- ANAPC15 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.339); catalogued as rs767356574, COSV99921529; called by muse, mutect2, varscan2
- ANAPC5 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs1028125388, COSV55844670; called by muse, mutect2, varscan2
- ANGPTL2 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568583240; called by muse, mutect2, varscan2
- ANGPTL4 | c.757+1G>A p.X253_splice | Splice Site (SNP) | VAF 28/70 reads (40%) | catalogued as rs576267013; called by muse, mutect2, varscan2
- ANK1 | c.4267C>T p.R1423W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1173387917; called by muse, mutect2, varscan2
- ANK2 | c.5539C>T p.P1847S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as rs1406342886, COSV52162999, COSV99999946; called by muse, varscan2
- ANK2 | c.5606C>T p.A1869V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs983680857, COSV52162757; called by muse, varscan2
- ANK3 | c.2029G>A p.V677M | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs761026357; called by muse, varscan2
- ANK3 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs1017693748; called by muse, varscan2
- ANK3 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344409291; called by muse, mutect2, varscan2
- ANKEF1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1367023488; called by muse, mutect2, varscan2
- ANKEF1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs757587718, COSV65693267; called by muse, mutect2, varscan2
- ANKEF1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs769016092; called by muse, mutect2, varscan2
- ANKEF1 | c.2082G>T p.K694N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV65693250, COSV65694056; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3670C>T p.R1224W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51853770; called by muse, mutect2, varscan2
- ANKLE2 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs528470040; called by muse, mutect2, varscan2
- ANKLE2 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1036751408; called by muse, mutect2, varscan2
- ANKMY1 | c.1621A>G p.N541D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs1320856970; called by muse, mutect2, varscan2
- ANKMY1 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360184495; called by muse, mutect2, varscan2
- ANKRD11 | c.7163G>A p.R2388H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56358957; called by muse, mutect2, varscan2
- ANKRD11 | c.4481G>A p.R1494Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV56375239; called by muse, mutect2, varscan2
- ANKRD11 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as COSV99970773; called by muse, mutect2, varscan2
- ANKRD11 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs144364610; called by muse, mutect2, varscan2
- ANKRD13C | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs779302047; called by muse, mutect2, varscan2
- ANKRD17 | c.2923G>A p.A975T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs770988706, COSV100428597; called by muse, mutect2, varscan2
- ANKRD24 | c.3061G>A p.A1021T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs758132672; called by mutect2, varscan2
- ANKRD26 | c.4976dup p.N1659Kfs*4 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | catalogued as rs762275496; called by mutect2, varscan2
- ANKRD28 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs779113898, COSV67516906; called by muse, mutect2, varscan2
- ANKRD30A | c.665G>A p.G222D (on ENST00000611781; = p.G166D on NM_052997.2) | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as rs371683302; called by muse, mutect2, varscan2
- ANKRD30A | c.904dup p.T302Nfs*3 (on ENST00000611781; = p.T246Nfs*3 on NM_052997.2) | Frame Shift Ins (INS) | VAF 25/95 reads (26%) | catalogued as rs755336380; called by mutect2, pindel, varscan2
- ANKRD33 | c.7G>A p.A3T (on ENST00000340970 / NM_001304459.2; = p.A138T on NM_182608.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs145080334; called by muse, mutect2, varscan2
- ANKRD34B | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs201143692; called by muse, mutect2, varscan2
- ANKRD36B | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1483515167; called by muse, mutect2, varscan2
- ANKRD36B | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1392452020; called by muse, mutect2, varscan2
- ANKRD50 | c.3857C>T p.A1286V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs778120664; called by mutect2, varscan2
- ANKRD50 | c.3235C>T p.R1079C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72386224; called by muse, mutect2, varscan2
- ANKRD50 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs764285889; called by muse, mutect2, varscan2
- ANKRD50 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1382943401, COSV72385901; called by muse, mutect2, varscan2
- ANKRD52 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as rs752844754; called by muse, mutect2, varscan2
- ANKRD54 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs763605893; called by muse, mutect2, varscan2
- ANKRD55 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1190937549; called by muse, mutect2, varscan2
- ANKS1A | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs146610677; called by muse, mutect2, varscan2
- ANKS1A | c.2866C>T p.R956* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs1300740333; called by muse, mutect2, varscan2
- ANKS3 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs200655172, COSV58508242; called by muse, mutect2, varscan2
- ANKS4B | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as rs763113188; called by muse, mutect2, varscan2
- ANKS6 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs199671276; called by muse, mutect2, varscan2
- ANKZF1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs761842964; called by muse, mutect2, varscan2
- ANO1 | c.2423C>T p.T808M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250438961; called by muse, mutect2, varscan2
- ANO1 | c.2806C>T p.R936W | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs201845370; called by muse, mutect2, varscan2
- ANO5 | c.2144A>G p.Q715R | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs886043450; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO5 | c.2521C>T p.H841Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781027702, CM137915, COSV61085947; called by muse, mutect2, varscan2
- ANO7 | c.1775T>C p.F592S (on ENST00000274979; = p.F538S on NM_001370694.2) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1380560864; called by muse, mutect2, varscan2
- ANO7 | c.2554G>A p.A852T (on ENST00000274979; = p.A798T on NM_001370694.2) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs139614449; called by muse, mutect2, varscan2
- ANO9 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.559); catalogued as rs765320102; called by muse, mutect2, varscan2
- ANOS1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as CM015286; called by muse, mutect2, varscan2
- AOX1 | c.3217C>T p.R1073C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs775339736, COSV53495680; called by muse, mutect2, varscan2
- AP002512.3 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV54406393; called by muse, mutect2, varscan2
- AP1B1 | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.776); catalogued as rs767707068; called by muse, mutect2, varscan2
- AP1B1 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1245595086, COSV100434853; called by muse, mutect2, varscan2
- AP1G1 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as rs774004811, COSV100250388; called by muse, mutect2, varscan2
- AP1G2 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757969661; called by muse, mutect2, varscan2
- AP1M1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52227400; called by muse, mutect2, varscan2
- AP1M2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs752536355; called by muse, mutect2, varscan2
- AP1M2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs747209644, COSV51568131; called by muse, mutect2, varscan2
- AP2A1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs375354389; called by muse, mutect2, varscan2
- AP2A1 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.272); catalogued as rs1213579233, COSV62820474; called by muse, mutect2, varscan2
- AP2A2 | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371126256; called by muse, varscan2
- AP2M1 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53047300, COSV99490552; called by muse, mutect2, varscan2
- AP3B2 | c.2561C>T p.P854L (on ENST00000261722; = p.P848L on NM_004644.5) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.151); catalogued as rs374804698; called by muse, mutect2, varscan2
- AP3D1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs935169340, COSV61431665; called by muse, mutect2, varscan2
- AP3M2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as rs984898613, COSV51531479; called by muse, mutect2, varscan2
- AP3S2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs776607280, COSV100318461; called by muse, mutect2, varscan2
- AP5Z1 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as rs778457903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBA1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs1453398803; called by muse, mutect2
- APBA2 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67104576; called by muse, mutect2, varscan2
- APBA3 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs911530503; called by muse, mutect2, varscan2
- APBB1 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs1394180630; called by muse, mutect2, varscan2
- APBB1IP | c.634C>A p.H212N | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63076082; called by muse, mutect2, varscan2
- APBB1IP | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63076067; called by muse, mutect2, varscan2
- APBB1IP | c.843del p.E282Kfs*9 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs1478302580; called by mutect2, pindel, varscan2
- APBB1IP | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752350360, COSV66131791; called by muse, mutect2, varscan2
- APC | c.8140C>T p.R2714C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs864622205, COSV57331764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.8324G>T p.G2775V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV57325333; called by muse, mutect2, varscan2
- APCDD1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.183); catalogued as rs1302943042, COSV62372722; called by muse, mutect2, varscan2
- APLP1 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as rs568306221, COSV55702927; called by muse, varscan2
- APLP2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149975560, COSV53840570; called by muse, mutect2, varscan2
- APOA5 | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1245663934; called by muse, mutect2, varscan2
- APOBEC3C | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs200232887, COSV53329192; called by muse, mutect2, varscan2
- APOBR | c.2876C>T p.T959M (on ENST00000431282; = p.T968M on NM_018690.4) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs369807816; called by muse, varscan2
- APOBR | c.2885C>T p.A962V (on ENST00000431282; = p.A971V on NM_018690.4) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100112779; called by muse, varscan2
- APOL4 | c.574G>A p.V192M (on ENST00000352371 / NM_145660.2; = p.V189M on NM_030643.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs373611761; called by muse, mutect2, varscan2
- APOL4 | c.380G>A p.R127H (on ENST00000352371 / NM_145660.2; = p.R124H on NM_030643.4) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs371910438; called by muse, mutect2, varscan2
- APP | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.607); catalogued as rs765907080; called by muse, mutect2, varscan2
- AQR | c.2395A>G p.T799A | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs750099471; called by muse, mutect2, varscan2
- AQR | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV50040181; called by muse, mutect2, varscan2
- AR | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1249267413; called by muse, mutect2, varscan2
- ARAP1 | c.1619G>A p.R540H (on ENST00000393609 / NM_001040118.2; = p.R295H on NM_015242.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs746910641, COSV61993762; called by muse, mutect2, varscan2
- ARAP1 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs755697030; called by muse, varscan2
- ARAP2 | c.965-1G>T p.X322_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV58282395, COSV58291435; called by muse, mutect2
- ARAP2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs199740529, COSV58285033; called by muse, mutect2, varscan2
- ARAP3 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1243860468; called by muse, mutect2, varscan2
- ARAP3 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1371259567, COSV53351745; called by muse, mutect2, varscan2
- AREL1 | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as rs762039755, COSV62666822; called by muse, mutect2, varscan2
- ARFGEF2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs778834589, COSV64211088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF3 | c.2968G>A p.V990I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs773124641, COSV52471408; called by muse, mutect2
- ARFIP2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as rs376794616; called by muse, mutect2, varscan2
- ARFIP2 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV54446838; called by muse, mutect2, varscan2
- ARFRP1 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs544032237, COSV53928763; called by muse, mutect2, varscan2
- ARHGAP11A | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as rs756869901, COSV64380781; called by muse, varscan2
- ARHGAP15 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs749157476, COSV54480561; called by muse, mutect2, varscan2
- ARHGAP17 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.25); catalogued as rs540145209; called by muse, varscan2
- ARHGAP17 | c.204dup p.L69Tfs*33 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | catalogued as rs1298232519; called by mutect2, pindel, varscan2
- ARHGAP19 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.039); catalogued as rs774211888; called by muse, mutect2, varscan2
- ARHGAP20 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as rs1191601571, COSV99503947, COSV99505675; called by muse, mutect2, varscan2
- ARHGAP20 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs745888650; called by muse, mutect2, varscan2
- ARHGAP21 | c.5567A>G p.E1856G | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs377439736; called by muse, mutect2, varscan2
- ARHGAP22 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs777718892, COSV99984611; called by muse, mutect2, varscan2
- ARHGAP22 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs755640836; called by muse, mutect2, varscan2
- ARHGAP24 | c.1448G>A p.R483H (on ENST00000395184 / NM_001025616.3; = p.R390H on NM_031305.3) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs116009088, COSV99982248; called by muse, mutect2, varscan2
- ARHGAP27 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1459471400; called by muse, mutect2, varscan2
- ARHGAP31 | c.3806C>T p.A1269V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs926263004, COSV51788630; called by muse, mutect2, varscan2
- ARHGAP32 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs369224664; called by muse, mutect2, varscan2
- ARHGAP35 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV68330848; called by muse, varscan2
- ARHGAP4 | c.2593G>A p.V865M | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs782606987; called by muse, mutect2, varscan2
- ARHGAP5 | c.2482C>T p.R828* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as rs1308729348, COSV61534750; called by muse, mutect2, varscan2
- ARHGAP6 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs899041025, COSV57299169; called by muse, mutect2, varscan2
- ARHGAP6 | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV104399443; called by muse, mutect2, varscan2
- ARHGDIB | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56762292; called by muse, mutect2, varscan2
- ARHGEF1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.184); catalogued as rs782629121, COSV61526661; called by muse, mutect2, varscan2
- ARHGEF1 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs782431103, COSV100528913; called by muse, mutect2, varscan2
- ARHGEF1 | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs782335508, COSV100529085; called by muse, mutect2, varscan2
- ARHGEF10 | c.2807C>T p.A936V (on ENST00000398564; = p.A911V on NM_014629.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); catalogued as rs759917045; called by muse, mutect2, varscan2
- ARHGEF10 | c.3977C>T p.A1326V (on ENST00000398564; = p.A1301V on NM_014629.4) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1248031400, COSV50642515; called by muse, mutect2
- ARHGEF10L | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs755899050, COSV51437482; called by muse, mutect2, varscan2
- ARHGEF10L | c.2972G>A p.R991Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747529935; called by muse, mutect2, varscan2
- ARHGEF10L | c.3611G>A p.S1204N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.24); catalogued as COSV99391962; called by muse, mutect2, varscan2
- ARHGEF11 | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1259740199; called by muse, mutect2, varscan2
- ARHGEF12 | c.2903G>A p.R968H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1364057590, COSV63104351; called by muse, varscan2
- ARHGEF15 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.866); catalogued as rs145017019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF17 | c.3946G>A p.V1316I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs370494524; called by muse, mutect2, varscan2
- ARHGEF17 | c.4630G>A p.A1544T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1331646167; called by muse, mutect2
- ARHGEF18 | c.1036C>T p.R346W (on ENST00000359920 / NM_001130955.2; = p.R242W on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762390589; called by muse, mutect2, varscan2
- ARHGEF26 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62843650; called by muse, mutect2, varscan2
- ARHGEF37 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs567909765, COSV61367758; called by muse, mutect2, varscan2
- ARHGEF4 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV58117128; called by muse, mutect2, varscan2
- ARHGEF5 | c.3571C>T p.R1191C | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560154773, COSV50209634; called by muse, mutect2, varscan2
- ARHGEF7 | c.449G>A p.R150H (on ENST00000375741 / NM_001113511.2; = p.R129H on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as rs780851372, COSV54538265; called by muse, varscan2
- ARHGEF7 | c.1226G>A p.R409H (on ENST00000375741 / NM_001113511.2; = p.R231H on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778093839, COSV54546717; called by muse, mutect2, varscan2
- ARID1B | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs151093357, COSV99273412; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARID3A | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs538606329, COSV55044793; called by muse, mutect2, varscan2
- ARID4A | c.2989C>T p.P997S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV62162308; called by muse, varscan2
- ARID4A | c.3049C>T p.R1017* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as rs1344759651, COSV62162823; called by muse, varscan2
- ARID5B | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99690455; called by muse, mutect2, varscan2
- ARIH1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs769846251; called by muse, mutect2, varscan2
- ARL6IP4 | c.1246C>T p.R416* (on ENST00000315580 / NM_018694.3; = p.R397* on NM_016638.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs547980550, COSV54898047; called by muse, mutect2, varscan2
- ARMC4 | c.2140G>A p.G714R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs866425433; called by muse, mutect2, varscan2
- ARMC6 | c.1237G>A p.G413R (on ENST00000392336; = p.G388R on NM_033415.4) | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1568498074, COSV99523084; called by muse, mutect2, varscan2
- ARMCX2 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV57529151; called by muse, mutect2, varscan2
- ARMH3 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409347423, COSV100899023; called by muse, mutect2, varscan2
- ARMH3 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as rs769392626, COSV100899005, COSV64234815; called by muse, mutect2, varscan2
- ARNT | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs754824680, COSV100591328; called by muse, mutect2, varscan2
- ARNT | c.934A>G p.I312V | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs759242068; called by muse, mutect2, varscan2
- ARNT2 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs757314385, COSV57588465; called by muse, mutect2, varscan2
- ARNTL | c.1033G>A p.A345T (on ENST00000403290 / NM_001297719.2; = p.A344T on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1348967130, COSV62985379; called by muse, mutect2, varscan2
- ARPIN | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs749897855; called by muse, mutect2, varscan2
- ARPP21 | c.1394T>C p.I465T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs202203517; called by muse, mutect2, varscan2
- ARSB | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs781369253; called by muse, mutect2, varscan2
- ARSD | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs772412380, COSV99472201; called by muse, mutect2, varscan2
- ARSH | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as rs759497002, COSV66962565; called by muse, mutect2, varscan2
- ARSH | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs759410833, COSV66963163; called by muse, mutect2, varscan2
- ARSL | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV66965403; called by muse, mutect2, varscan2
- ARTN | c.92C>T p.A31V (on ENST00000372354; = p.A39V on NM_057090.2) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1418161602; called by muse, mutect2, varscan2
- ARVCF | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.885); catalogued as COSV54268606; called by muse, mutect2, varscan2
- ASAH2 | c.148dup p.S50Ffs*61 | Frame Shift Ins (INS) | VAF 43/141 reads (30%) | catalogued as rs772181094; called by mutect2, varscan2
- ASB1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1362856701, COSV52828594; called by muse, mutect2, varscan2
- ASB1 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs781739770, COSV52827589; called by muse, mutect2, varscan2
- ASB15 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51927702; called by muse, mutect2, varscan2
- ASB16 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as rs1373310670; called by muse, mutect2, varscan2
- ASB4 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV57943878; called by muse, mutect2, varscan2
- ASB6 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764592974, COSV52964890; called by muse, mutect2, varscan2
- ASB7 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV58404655; called by muse, mutect2, varscan2
- ASB8 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs565893897; called by muse, mutect2, varscan2
- ASCC3 | c.5284C>T p.R1762C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138910225, COSV64981462; called by muse, mutect2, varscan2
- ASCC3 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178562524; called by muse, mutect2, varscan2
- ASGR2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as rs534502192; called by muse, mutect2, varscan2
- ASH1L | c.8872C>T p.R2958C (on ENST00000368346 / NM_001366177.2; = p.R2953C on NM_018489.3) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1375751864, COSV64213624; called by muse, mutect2, varscan2
- ASMTL | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs748954134; called by muse, mutect2, varscan2
- ASPDH | c.782T>C p.V261A (on ENST00000389208 / NM_001114598.2; = p.V156A on NM_001024656.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs200717735; called by muse, mutect2, varscan2
- ASPH | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as rs1306079293; called by muse, mutect2, varscan2
- ASPH | c.118G>T p.G40* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV62858986; called by muse, mutect2, varscan2
- ASPHD2 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1450597703, COSV53221267; called by muse, mutect2, varscan2
- ASPM | c.9243dup p.S3082Ifs*42 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | catalogued as rs749449214; called by mutect2, pindel, varscan2
- ASPM | c.8938G>A p.A2980T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs1396209733; called by muse, varscan2
- ASPM | c.4175G>A p.R1392Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.234); catalogued as rs765050426, COSV99660792; called by muse, mutect2, varscan2
- ASTN2 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV100530066; called by muse, mutect2, varscan2
- ASXL3 | c.4103G>A p.R1368K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52458996; called by muse, mutect2, varscan2
- ATAD2 | c.3883C>T p.R1295* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as rs1309068218, COSV54881315; called by muse, mutect2, varscan2
- ATAD2 | c.3646G>A p.G1216R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs761962234, COSV99075296; called by muse, varscan2
- ATAD2B | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as rs761265177; called by muse, mutect2, varscan2
- ATAD3A | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs376902508, COSV59234839; called by muse, mutect2, varscan2
- ATAD5 | c.3688C>T p.R1230* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100429593; called by muse, mutect2, varscan2
- ATCAY | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1382365615, COSV56655194; called by muse, mutect2, varscan2
- ATF3 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs753810336, COSV100422089; called by muse, mutect2, varscan2
- ATF4 | c.620G>A p.C207Y | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.556); catalogued as rs777575460; called by muse, mutect2, varscan2
- ATF6 | c.930G>T p.Q310H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100909524; called by muse, mutect2, varscan2
- ATF7IP | c.302dup p.N101Kfs*5 | Frame Shift Ins (INS) | VAF 10/25 reads (40%) | catalogued as rs1460828096; called by mutect2, pindel, varscan2
- ATF7IP | c.1292A>G p.E431G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1487567011; called by muse, mutect2, varscan2
- ATF7IP | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs545457346; called by muse, mutect2, varscan2
- ATF7IP | c.2495C>A p.P832Q | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as COSV99662052; called by muse, mutect2, varscan2
- ATG2A | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs202213951, COSV65969349; called by muse, mutect2, varscan2
- ATG2A | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs144251049; called by muse, mutect2, varscan2
- ATG2B | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs373581781; called by muse, mutect2, varscan2
- ATG3 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as rs776484326; called by muse, mutect2, varscan2
- ATG4A | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs745864237, COSV58964155; called by muse, mutect2, varscan2
- ATM | c.7075A>T p.T2359S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV99592906; called by muse, mutect2, varscan2
- ATP10A | c.2635C>A p.R879S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63512846, COSV63515586; called by muse, mutect2, varscan2
- ATP10B | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as rs201139624, COSV100469476; called by muse, mutect2, varscan2
- ATP10D | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs371299383; called by muse, mutect2, varscan2
- ATP11A | c.2827G>A p.V943M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs188933573; called by muse, mutect2, varscan2
- ATP11A | c.3113C>T p.S1038L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1451569881, COSV52106942; called by muse, mutect2, varscan2
- ATP12A | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs370861260; called by muse, mutect2, varscan2
- ATP13A1 | c.3451G>A p.G1151S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.838); catalogued as rs1239647244, COSV99179374; called by muse, mutect2
- ATP13A1 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as rs1186399747; called by muse, mutect2, varscan2
- ATP13A2 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs973767624; called by muse, varscan2
- ATP1A1 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV55191560; called by muse, mutect2, varscan2
- ATP1A4 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs750851195, COSV63625375; called by muse, mutect2, varscan2
- ATP2A1 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs779457144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A3 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); catalogued as rs374111599, COSV99989448; called by muse, mutect2, varscan2
- ATP2B1 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53808088; called by muse, varscan2
- ATP2B1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53814233; called by muse, varscan2
- ATP2B2 | c.2921C>T p.A974V (on ENST00000352432; = p.A940V on NM_001683.5) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); catalogued as rs751257556; called by muse, mutect2, varscan2
- ATP2B3 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs781860414, COSV54855874; called by muse, varscan2
- ATP2C2 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372231003; called by muse, mutect2, varscan2
- ATP4A | c.2329C>T p.R777* | Nonsense Mutation (SNP) | VAF 36/69 reads (52%) | catalogued as rs1472525962, COSV52869591; called by muse, mutect2, varscan2
- ATP4A | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as rs1382227785; called by muse, mutect2, varscan2
- ATP4A | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52872723; called by muse, mutect2, varscan2
- ATP4A | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs746484584, COSV52865275; called by muse, mutect2
- ATP5F1A | c.953C>A p.A318D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56361707, COSV99959117; called by muse, mutect2, varscan2
- ATP5F1C | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as rs1415391887; called by muse, mutect2, varscan2
- ATP5MC1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs753944444, COSV63506024; called by muse, mutect2, varscan2
- ATP5PO | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs191960490; called by muse, mutect2, varscan2
- ATP6AP2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs761302416, COSV65797564; called by muse, mutect2, varscan2
- ATP6V0E2 | c.181A>G p.N61D (on ENST00000425642; = p.N110D on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1306933671; called by muse, mutect2, varscan2
- ATP6V1A | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.486); catalogued as rs749209409, COSV99850211; called by muse, mutect2, varscan2
- ATP6V1C2 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs374055141; called by muse, mutect2, varscan2
- ATP6V1E2 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV60576197; called by muse, mutect2, varscan2
- ATP6V1H | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs779088847; called by muse, mutect2, varscan2
- ATP7A | c.1271T>C p.L424P | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.908); catalogued as rs782358866; called by muse, mutect2, varscan2
- ATP7A | c.1735G>A p.V579I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs372116692, COSV58444588; called by muse, mutect2, varscan2
- ATP7B | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs755463471; called by muse, mutect2, varscan2
- ATP8A1 | c.3193C>A p.L1065I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52547801; called by muse, mutect2, varscan2
- ATP8B1 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs757716772, COSV99376998; called by muse, mutect2, varscan2
- ATP8B1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.851); catalogued as rs372749108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B2 | c.437G>A p.R146H (on ENST00000672630; = p.R113H on NM_001005855.2) | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1259824646, COSV59245718; called by muse, mutect2, varscan2
- ATP8B2 | c.635C>T p.A212V (on ENST00000672630; = p.A179V on NM_001005855.2) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1393418645, COSV59245573; called by muse, mutect2, varscan2
- ATP8B3 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs542432405; called by muse, mutect2, varscan2
- ATP8B4 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs200106056, COSV52713293; called by muse, mutect2, varscan2
- ATP9B | c.3072C>T p.G1024= | Splice Region (SNP) | VAF 18/64 reads (28%) | catalogued as rs149975826; called by muse, varscan2
- ATRN | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs770734526; called by muse, mutect2, varscan2
- ATRX | c.5093G>A p.R1698Q | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV64872200; called by muse, mutect2, varscan2
- ATRX | c.1397G>T p.R466I | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV64878777; called by muse, mutect2, varscan2
- ATXN1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs750197520; called by muse, mutect2, varscan2
- ATXN2 | c.3587C>T p.A1196V (on ENST00000550104; = p.A1036V on NM_002973.4) | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773079127, COSV57981143; called by muse, mutect2, varscan2
- ATXN3 | c.224dup p.S76Lfs*34 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | catalogued as rs763008544; called by pindel, varscan2
- ATXN3L | c.585del p.K195Nfs*2 | Frame Shift Del (DEL) | VAF 26/57 reads (46%) | catalogued as rs1411781059; called by mutect2, pindel, varscan2
- ATXN7L3 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.159); catalogued as rs75308141; called by muse, mutect2, varscan2
- AURKC | c.724G>A p.A242T (on ENST00000302804 / NM_001015878.2; = p.A208T on NM_003160.3) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs762552612; called by muse, mutect2, varscan2
- AUTS2 | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.748); catalogued as rs750630131; called by muse, mutect2
- AUTS2 | c.3232C>T p.P1078S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1169875410; called by muse, mutect2, varscan2
- AVIL | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs765836504; called by muse, mutect2, varscan2
- AVIL | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs146185696; called by muse, mutect2, varscan2
- AVIL | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201937160; called by muse, mutect2, varscan2
- AVIL | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs183869010; called by muse, mutect2, varscan2
- AVL9 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as rs759557265, COSV59464560; called by muse, mutect2, varscan2
- AVPR1B | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs376650205; called by muse, mutect2, varscan2
- AXDND1 | c.2851G>A p.E951K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs772530889, COSV62643802; called by muse, mutect2, varscan2
- AXIN2 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61055422; called by muse, mutect2, varscan2
- B3GALT1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs1243246622, COSV59907953; called by muse, mutect2, varscan2
- B3GAT1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs746141520; called by muse, mutect2, varscan2
- B3GNT4 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs1394031528, COSV57338292; called by muse, mutect2, varscan2
- B3GNT8 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs762148606, COSV54200237; called by muse, mutect2, varscan2
- B4GALNT1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs778379778; called by muse, mutect2, varscan2
- B4GALNT1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs139453491, COSV57541086; called by muse, mutect2, varscan2
- B4GALNT4 | c.783C>T p.G261= | Splice Region (SNP) | VAF 16/39 reads (41%) | catalogued as rs147162160; called by muse, mutect2, varscan2
- B4GALNT4 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV57326114; called by muse, mutect2, varscan2
- B4GALNT4 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs759064827, COSV57322670; called by muse, mutect2, varscan2
- B4GALT6 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs776343053; called by muse, mutect2, varscan2
- B4GALT7 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs765468044; called by muse, mutect2, varscan2
- BAAT | c.374G>C p.S125T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs769234439; called by muse, mutect2, varscan2
- BACE2 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs531921336, COSV57737876; called by muse, mutect2, varscan2
- BACE2 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV57739721; called by muse, mutect2, varscan2
- BACH1 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV54519384; called by muse, mutect2, varscan2
- BACH1 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1569017478, COSV54517670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAG5 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs182208325, COSV54570184; called by muse, mutect2, varscan2
- BAG6 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99277306; called by muse, mutect2, varscan2
- BAHD1 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs766129464; called by muse, mutect2, varscan2
- BAIAP2L1 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs768829897; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1504C>A p.L502I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs779109789; called by muse, mutect2, varscan2
- BAIAP3 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs145863608; called by muse, mutect2, varscan2
- BAIAP3 | c.1617-1G>T p.X539_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as rs771469154; called by muse, mutect2, varscan2
- BAK1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.083); catalogued as rs1417013867, COSV62349247, COSV62349385; called by muse, mutect2, varscan2
- BANP | c.1055C>T p.T352I (on ENST00000286122; = p.T321I on NM_017869.4) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.312); catalogued as rs777424904; called by muse, varscan2
- BAP1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1284965361, COSV99964338; called by muse, mutect2, varscan2
- BAP1 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs951076425; ClinVar: uncertain significance; called by muse, varscan2
- BARHL1 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.055); catalogued as COSV99707452; called by muse, mutect2
- BAZ1A | c.4339C>T p.R1447* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs765397590; called by muse, mutect2, varscan2
- BAZ1A | c.2839C>T p.P947S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs747659465; called by muse, mutect2, varscan2
- BAZ1A | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as rs1002728523; called by muse, mutect2, varscan2
- BAZ2A | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs953950184; called by muse, mutect2, varscan2
- BAZ2B | c.2582G>T p.R861M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs376009852; called by muse, mutect2, varscan2
- BBS4 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs969384648, COSV51439185; called by muse, mutect2, varscan2
- BCAT2 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs752836872, COSV60271860; called by muse, mutect2, varscan2
- BCAT2 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60274023; called by muse, mutect2
- BCCIP | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs182757952; called by muse, mutect2, varscan2
- BCKDK | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as rs755953122, COSV54892608; called by muse, mutect2, varscan2
- BCKDK | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139044149; called by muse, mutect2, varscan2
- BCL2L11 | c.481G>A p.A161T (on ENST00000393256 / NM_138621.5; = p.A101T on NM_006538.5) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as rs757046249, COSV100427445; called by muse, mutect2, varscan2
- BCL2L12 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs1428171520; called by muse, mutect2, varscan2
- BCL2L2 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs41317322, COSV51637077; called by mutect2, varscan2
- BCL6B | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs769200715, COSV53428344; called by muse, mutect2, varscan2
- BCL7B | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.255); catalogued as rs782766469; called by muse, mutect2, varscan2
- BCLAF3 | c.2036G>A p.R679H (on ENST00000379682 / NM_001367774.1; = p.R650H on NM_198279.3) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs774005570; called by muse, mutect2, varscan2
- BCLAF3 | c.1882G>T p.D628Y (on ENST00000379682 / NM_001367774.1; = p.D599Y on NM_198279.3) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV61414984; called by muse, mutect2, varscan2
- BCO2 | c.1516-1G>T p.X506_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as COSV63063849; called by muse, mutect2, varscan2
- BCOR | c.2288G>A p.R763Q | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); catalogued as rs139011455, COSV60714702, COSV60723729; called by muse, mutect2, varscan2
- BCORL1 | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1170265378, COSV99498959; called by muse, mutect2, varscan2
- BDH1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178948970; called by muse, mutect2, varscan2
- BDP1 | c.4817C>T p.T1606M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1465541848, COSV100702662; called by muse, mutect2, varscan2
- BEND3 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.347); catalogued as rs782613092, COSV64682576; called by muse, mutect2, varscan2
- BEST3 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766338045, COSV56993729, COSV56995604; called by muse, varscan2
- BFAR | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs768962951; called by muse, mutect2
- BGN | c.404G>A p.S135N | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.1); catalogued as rs1556992993; called by muse, mutect2, varscan2
- BHLHA15 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774688814; called by muse, mutect2, varscan2
- BICC1 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs759875498, COSV54063715; called by muse, varscan2
- BICC1 | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749021662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICD2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs762910297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICRA | c.2795C>T p.P932L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as rs777562135, COSV67606324; called by muse, mutect2, varscan2
- BICRAL | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as rs754684568, COSV58404699; called by muse, mutect2, varscan2
- BICRAL | c.2356A>G p.N786D | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs373658559; called by muse, mutect2, varscan2
- BIN3 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs750251598, COSV52384460; called by muse, mutect2, varscan2
- BIRC6 | c.6605G>A p.S2202N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.823); catalogued as rs776988295; called by muse, mutect2, varscan2
- BIRC6 | c.10996C>T p.R3666C | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs61757639, COSV101428129; called by muse, mutect2, varscan2
- BIRC6 | c.13798C>T p.R4600C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs773885941, COSV101428443; called by muse, mutect2, varscan2
- BIRC7 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs778417811, COSV53902209; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3098G>A p.G1033D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100863942; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3745G>A p.A1249T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751772171, CM162693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3982G>A p.A1328T | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434576, CM025988, COSV63246549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLK | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs1013048438, COSV52056498; called by muse, mutect2, varscan2
- BLOC1S6 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as rs779690168; called by muse, mutect2, varscan2
- BLVRA | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs377670975; called by muse, mutect2, varscan2
- BMP1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs767453320, COSV60482223; called by muse, mutect2, varscan2
- BMP15 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs782306478; called by muse, mutect2, varscan2
- BMP2 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66578549; called by muse, mutect2, varscan2
- BMP2K | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as rs1273646534; called by muse, mutect2, varscan2
- BMP7 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.312); catalogued as rs764633584, COSV67780354; called by muse, mutect2, varscan2
- BMS1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs374294179; called by muse, mutect2, varscan2
- BMS1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766620569, COSV100996898; called by muse, mutect2, varscan2
- BOC | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as rs761303691, COSV56357892; called by muse, varscan2
- BOD1L1 | c.7532C>T p.T2511M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs754054463; called by muse, mutect2, varscan2
- BPIFB2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs144321606, COSV99401428; called by muse, mutect2, varscan2
- BPIFB3 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs561454593; called by muse, mutect2, varscan2
- BPNT1 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757240318, COSV59040651; called by muse, mutect2, varscan2
- BPTF | c.5815G>A p.E1939K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs780605303, COSV58845552; called by muse, mutect2, varscan2
- BRCA2 | c.3908G>A p.G1303D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.104); catalogued as rs587782645; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.4534C>T p.R1512C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs80358684, COSV66461184; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.172); catalogued as rs80358685, CD063459, COSV66459060; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.5867A>G p.D1956G | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1309562690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.10150C>T p.R3384* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs397507568, CM063881, COSV66336867; ClinVar: likely benign / conflicting interpretations of pathogenicity / benign / uncertain significance; called by muse, mutect2, varscan2
- BRCC3 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.876); catalogued as COSV57463305; called by muse, mutect2, varscan2
- BRD1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99350149; called by muse, mutect2, varscan2
- BRD2 | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1460701811; called by muse, mutect2, varscan2
- BRD3 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs201977681; called by muse, mutect2, varscan2
- BRD4 | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as rs150583855; called by muse, mutect2, varscan2
- BRINP1 | c.1661G>T p.S554I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as COSV56300442; called by muse, mutect2, varscan2
- BRPF1 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs1359599082, COSV57407553; called by muse, mutect2, varscan2
- BSN | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1336122554; called by muse, mutect2, varscan2
- BSN | c.7186C>T p.R2396W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs774693300; called by muse, mutect2, varscan2
- BSN | c.7682G>A p.R2561H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753587578, COSV99609140; called by muse, mutect2, varscan2
- BSN | c.10304G>A p.R3435H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs559401458, COSV56515702; called by muse, mutect2, varscan2
14,565 further variants in this file (10,153 protein-altering or splice-affecting, 4,099 silent, 313 other) are not listed here.
